Somatic mutation profile of tumor specimen TCGA-62-8397-01A (aliquot TCGA-62-8397-01A-11D-2323-08) from TCGA case TCGA-62-8397, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.4 years (25,728 days).
Specimen TCGA-62-8397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ca71ae5-bad9-4142-b00e-d9f74250bb62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-8397-10A (Blood Derived Normal), aliquot TCGA-62-8397-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/683b789b-dd99-4358-abb1-d345ddaf7cbb

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303_2311dup p.S768_D770dup | In Frame Ins (INS) | VAF 50/156 reads (32%) | hotspot (GDC flag); catalogued as rs397517109; ClinVar: likely pathogenic / drug response; called by mutect2, varscan2
- ADAMTS6 | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 30/59 reads (51%) | catalogued as rs1267132639, COSV66856691; called by muse, mutect2, varscan2
- ADGRB3 | c.2971C>A p.P991T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53235067, COSV53239260; called by muse, mutect2, varscan2
- C8A | c.784T>A p.L262M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100776563; called by muse, mutect2, varscan2
- CSF1R | c.1713C>A p.Y571* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as COSV99642382; called by muse, mutect2, varscan2
- EFR3A | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99603190; called by muse, mutect2, varscan2
- FN1 | c.7153del p.R2385Efs*24 (on ENST00000359671 / NM_001365524.2; = p.R2354Efs*24 on NM_002026.4) | Frame Shift Del (DEL) | VAF 26/152 reads (17%) | catalogued as COSV60561151; called by mutect2, pindel, varscan2
- GPATCH8 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100132718; called by muse, mutect2, varscan2
- GPATCH8 | c.194-1G>T p.X65_splice | Splice Site (SNP) | VAF 27/39 reads (69%) | catalogued as COSV100132720; called by muse, mutect2, varscan2
- IFNA21 | c.552A>T p.R184S | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV101207428; called by muse, mutect2, varscan2
- IGSF1 | c.1793C>T p.T598I | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100812172; called by muse, mutect2, varscan2
- NUDCD3 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100819379; called by muse, mutect2, varscan2
- NUTM2D | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780066522, COSV67746657; called by muse, mutect2, varscan2
- OR52J3 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV66747154; called by muse, mutect2, varscan2
- PBX4 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99232294; called by muse, mutect2, varscan2
- RLBP1 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV99175350; called by muse, mutect2, varscan2
- SCN11A | c.3550G>C p.V1184L | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100181855; called by muse, mutect2, varscan2
- SEC63 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100938429; called by muse, mutect2, varscan2
- SPG11 | c.1867A>C p.K623Q | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.292); catalogued as COSV99969014; called by muse, mutect2, varscan2
- ZMYND11 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100556644; called by muse, varscan2
- KMT2D | c.6868del p.E2290Kfs*32 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- POMZP3 | c.26_28del p.R9del | In Frame Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- PXDN | c.4358dup p.A1454Cfs*42 | Frame Shift Ins (INS) | VAF 7/18 reads (39%) | called by mutect2, pindel, varscan2
- DOCK3 | c.879G>T p.V293= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99813225, COSV99815188; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1314C>T p.R438= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs761989548, COSV100668678; called by muse, mutect2, varscan2
- FAM71E1 | c.171G>A p.P57= | Silent (SNP) | VAF 47/80 reads (59%) | catalogued as COSV100618513; called by muse, mutect2, varscan2
- MIEF2 | c.1272C>T p.S424= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as rs763610080, COSV100544117; called by muse, mutect2, varscan2
- PHKA2 | c.753A>T p.T251= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV101177214; called by muse, mutect2, varscan2
- RLBP1 | c.417C>T p.T139= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV51528854, COSV99175351; called by muse, mutect2, varscan2
- SALL1 | c.1083G>A p.G361= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV99174903; called by muse, mutect2, varscan2
